Somatic mutation profile of tumor specimen TCGA-28-5209-01A (aliquot TCGA-28-5209-01A-01D-1486-08) from TCGA case TCGA-28-5209, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.7 years (24,362 days).
Specimen TCGA-28-5209-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98209cc6-a517-47eb-a5e0-53dfbac9b6fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5209-10A (Blood Derived Normal), aliquot TCGA-28-5209-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5ea864b-48c9-48f1-b05b-076377bc0b48

The open-access MAF lists 85 somatic variants for this specimen: 65 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Nonsense Mutation 6, Frame Shift Del 4, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>C p.G598A | Missense Mutation (SNP) | VAF 432/3591 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.723dup p.E242* | Frame Shift Ins (INS) | VAF 96/161 reads (60%) | catalogued as rs1060500115; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SPG11 | c.6856C>T p.R2286* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as rs312262785, CM091369, COSV55998184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.9577C>T p.R3193* (on ENST00000591111; = p.R3147* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 89/218 reads (41%) | catalogued as rs746115846, CM157289, COSV59949359; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1093T>C p.Y365H | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV55937739; called by muse, mutect2, varscan2
- ABCC9 | c.3557G>A p.R1186Q | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776973456, COSV53977476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAD11 | c.398C>G p.T133R | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.826); catalogued as COSV53898552; called by muse, mutect2, varscan2
- ACSM2A | c.1469A>T p.E490V (on ENST00000219054; = p.E411V on NM_001308169.2) | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54586615; called by muse, mutect2, varscan2
- ADAD1 | c.709T>C p.F237L | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV56644973; called by muse, mutect2, varscan2
- ARMC4 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 60/65 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs556371991, COSV100537198, COSV59467284; called by muse, mutect2, varscan2
- ATP2A3 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1232687904, COSV59230124; called by muse, mutect2
- BORCS6 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101197997; called by muse, mutect2, varscan2
- BORCS6 | c.814G>T p.G272* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV101197998; called by muse, mutect2, varscan2
- BRWD3 | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 115/359 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV64750579; called by muse, mutect2, varscan2
- C5AR1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as rs201037165; called by muse, mutect2, varscan2
- CACNA1D | c.5535T>G p.Y1845* (on ENST00000350061 / NM_001128840.3; = p.Y1865* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 202/420 reads (48%) | catalogued as COSV55454635; called by muse, mutect2, varscan2
- CALN1 | c.565G>A p.V189I (on ENST00000329008 / NM_001017440.3; = p.V231I on NM_031468.4) | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs144352678; called by muse, mutect2, varscan2
- CD33 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs150408980, COSV99220713; called by muse, mutect2, varscan2
- CHP2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773423633, COSV55649193; called by muse, mutect2, varscan2
- CLEC4E | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs201571010, COSV55226447; called by muse, mutect2, varscan2
- COL1A2 | c.2809G>T p.G937C | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72659309, CM070783, COSV51961112, COSV51963189; called by muse, mutect2, varscan2
- COPB1 | c.1434G>T p.E478D | Missense Mutation (SNP) | VAF 140/307 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.374); catalogued as COSV51449342, COSV51450384; called by muse, mutect2, varscan2
- DEFB114 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as rs577162073, COSV59037123; called by muse, mutect2, varscan2
- DPPA3 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as rs571145972, COSV61502979; called by muse, varscan2
- DSCAML1 | c.3089G>A p.R1030H (on ENST00000321322; = p.R970H on NM_020693.4) | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs758642341, COSV58395976; called by muse, mutect2, varscan2
- FCER1A | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 226/507 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142162478, COSV63668721; called by muse, mutect2, varscan2
- FLT3 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs572460566, COSV54060003; called by muse, mutect2, varscan2
- FOXG1 | c.700T>G p.S234A | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM113877, COSV57395902, COSV57397963; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 147/360 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1158230332; called by muse, mutect2, varscan2
- KLF5 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV66614859; called by muse, mutect2, varscan2
- LAMA1 | c.7079G>T p.R2360L | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV67539741, COSV67539971; called by muse, mutect2, varscan2
- LRP4 | c.2876A>G p.Y959C | Missense Mutation (SNP) | VAF 115/236 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66136931; called by muse, mutect2, varscan2
- MAN2B1 | c.2448G>C p.R816S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747744816, COSV55473258; called by muse, mutect2, varscan2
- MKRN2 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 108/237 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50105939; called by muse, mutect2, varscan2
- MMP27 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 143/304 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52781640; called by muse, mutect2, varscan2
- MST1R | c.695T>A p.F232Y | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56570700; called by muse, mutect2, varscan2
- MTMR1 | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV64898812; called by muse, mutect2, varscan2
- NPHS1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.675); catalogued as COSV62288804; called by muse, mutect2, varscan2
- NRK | c.2346T>G p.I782M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV54600715; called by muse, mutect2, varscan2
- PCDHGB3 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs569737317, COSV53912080; called by muse, mutect2, varscan2
- PDHA2 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 64/159 reads (40%) | catalogued as rs755333932, COSV54777202; called by muse, mutect2, varscan2
- PEG3 | c.3337G>A p.G1113S | Missense Mutation (SNP) | VAF 115/464 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs771243590, COSV55638977; called by muse, mutect2, varscan2
- PI4K2A | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 66/75 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV65701782; called by muse, mutect2, varscan2
- PLA2G4A | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV66555052; called by muse, mutect2, varscan2
- PLEKHG2 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.169); catalogued as COSV52686247; called by muse, mutect2, varscan2
- PROKR2 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs761425593, COSV54084959, COSV54084982; called by muse, mutect2, varscan2
- PROKR2 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs146963803, CM119302; called by muse, mutect2, varscan2
- RASGRF2 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV54122528; called by muse, mutect2, varscan2
- SEMA3E | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 39/143 reads (27%) | catalogued as rs965528935, COSV57082291; called by muse, mutect2, varscan2
- SLC22A5 | c.1633G>T p.G545C | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV55373794; called by muse, mutect2, varscan2
- SLC38A7 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs754254080, COSV54702410; called by muse, mutect2, varscan2
- SPAG17 | c.3496G>T p.V1166F | Missense Mutation (SNP) | VAF 110/278 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs766904011, COSV60461591; called by muse, mutect2, varscan2
- SUCLA2 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV66222474; called by muse, mutect2, varscan2
- SVOPL | c.1271C>T p.P424L (on ENST00000419765; = p.P272L on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55992973; called by muse, mutect2, varscan2
- TRHDE | c.2731T>A p.S911T | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53852555; called by muse, mutect2, varscan2
- TRIM6 | c.509C>A p.T170K | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV53475960; called by muse, mutect2, varscan2
- ZC3H12B | c.1627C>A p.H543N | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.272); catalogued as COSV59049406; called by muse, mutect2, varscan2
- ZNF157 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs760600482, COSV65659233; called by muse, mutect2, varscan2
- ZNF280A | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 154/306 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs780225696, COSV57480372; called by muse, mutect2, varscan2
- ZNF358 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1182063381, COSV51177476; called by muse, mutect2
- ZNF543 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58628404; called by muse, mutect2, varscan2
- AKR7A3 | c.639del p.D213Efs*51 | Frame Shift Del (DEL) | VAF 104/299 reads (35%) | called by mutect2, pindel, varscan2
- DOCK11 | c.3168del p.D1058Ifs*25 | Frame Shift Del (DEL) | VAF 110/191 reads (58%) | called by mutect2, pindel, varscan2
- RNF168 | c.169_170del p.R57Gfs*34 | Frame Shift Del (DEL) | VAF 39/168 reads (23%) | called by mutect2, pindel, varscan2
- TAOK1 | c.16_28del p.R6* | Frame Shift Del (DEL) | VAF 41/110 reads (37%) | called by mutect2, pindel, varscan2
- ABCG2 | c.228C>T p.N76= | Silent (SNP) | VAF 106/236 reads (45%) | catalogued as rs772040991, COSV52947333; called by muse, mutect2, varscan2
- ADCY6 | c.3213G>A p.K1071= | Silent (SNP) | VAF 705/873 reads (81%) | catalogued as COSV57168941, COSV57170244; called by muse, mutect2, varscan2
- ADGRE2 | c.1581C>T p.Y527= | Silent (SNP) | VAF 86/263 reads (33%) | catalogued as rs754549569, COSV59694616, COSV59694704; called by muse, mutect2, varscan2
- AEBP1 | c.495G>A p.P165= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs144974496; called by muse, mutect2, varscan2
- AFG3L2 | c.1398G>A p.P466= | Silent (SNP) | VAF 59/170 reads (35%) | catalogued as rs547346676, COSV52315741; called by muse, mutect2, varscan2
- BTRC | c.144C>T p.L48= | Silent (SNP) | VAF 62/83 reads (75%) | catalogued as COSV64560559; called by muse, mutect2, varscan2
- GPATCH1 | c.471C>T p.F157= | Silent (SNP) | VAF 82/233 reads (35%) | catalogued as rs149673951; called by muse, mutect2, varscan2
- GPR174 | c.561C>A p.T187= | Silent (SNP) | VAF 115/251 reads (46%) | catalogued as COSV52133229; called by muse, mutect2, varscan2
- ICAM1 | c.366C>T p.P122= | Silent (SNP) | VAF 109/352 reads (31%) | catalogued as COSV53425919; called by muse, mutect2, varscan2
- ITGB2 | c.816C>T p.D272= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs779979379, COSV56611395; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITPRID1 | c.1521G>A p.L507= | Silent (SNP) | VAF 113/383 reads (30%) | catalogued as COSV60076668, COSV60077689; called by muse, mutect2, varscan2
- MS4A15 | c.15C>T p.P5= | Silent (SNP) | VAF 134/299 reads (45%) | catalogued as rs372949576; called by muse, mutect2, varscan2
- MTERF2 | c.1157G>A p.*386= | Silent (SNP) | VAF 87/212 reads (41%) | catalogued as COSV53527935; called by muse, mutect2, varscan2
- PCSK2 | c.1032C>T p.D344= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as rs1193757704, COSV52726778, COSV52734911; called by muse, mutect2, varscan2
- PLXNB3 | c.591G>A p.S197= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs782468929, COSV62799117; called by muse, mutect2, varscan2
- SLFN13 | c.1539G>A p.K513= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as COSV99539935; called by muse, mutect2, varscan2
- SUV39H1 | c.1074C>T p.G358= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV61920992; called by muse, mutect2, varscan2
- SYNJ2 | c.984C>T p.G328= | Silent (SNP) | VAF 267/315 reads (85%) | catalogued as rs142499089; called by muse, mutect2, varscan2
- ZNF98 | c.315A>G p.Q105= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV63337719; called by muse, mutect2, varscan2
- SH2B2 | chr7:102282768 C>T | 5'Flank (SNP) | VAF 17/110 reads (15%) | catalogued as rs781838453, COSV52926110; called by muse, mutect2, varscan2
